CPTAC case C3N-00550 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46be30d5-b623-4469-a1d3-fbc76a62cca5

Demographics
Sex at birth: female; Race: asian; Year of birth: 1964; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 52.3 years (19,107 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 401 days (1.1 years); Progression or recurrence: no; Days to last follow up: 401 days (1.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm (a second GDC size field records 4.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 20; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 401 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 2.

Other clinical attributes
- Weight: 72 kg; Height: 173 cm; BMI: 24.06.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (10 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-00550-01, C3N-00550-03, C3N-00550-04 (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 300 mg.
- Sample C3N-00550-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 5 days; Initial weight: 300 mg; Time between clamping and freezing: 15 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00550-22: Section location: Left Lower Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-00550-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 5 days; Initial weight: 150 mg; Time between clamping and freezing: 20 minutes; Time between excision and freezing: 7 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00550-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 150 mg.
- Samples C3N-00550-31, C3N-00550-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-00550-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 5 days; Method of sample procurement: Blood Draw.
- Sample C3N-00550-72: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
